Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4903, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4903-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4903

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S NUCLEAR GRADE 3.

TUMOR CONFINED TO THE KIDNEY.

TUMOR MEASURES 5.0 CM IN MAXIMUM DIMENSION.

Vascular, ureteral and soft tissue margins of resection free of tumor.

Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A nephrectomy specimen (19.0 x 10.0 x 5.7 cm) including the left kidney (12.0 x 7.5 x 5.0 cm), a segment of renal artery, the renal vein, ureter (8.5 cm in length and 0.4 cm in diameter) and the adrenal gland (6.0 x 1.7 x 0.5 cm).

There is a 5.0 x 3.7 x 3.2 cm well-circumscribed tumor in the upper pole of the kidney. The tumor is bright yellow-tan with extensive central, gray-tan myxoid change. The tumor is confined to the kidney and does not invade into the perinephric adipose tissue, renal sinus or renal vein. The tumor does not extend to the Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvic calyceal system is smooth and devoid of any lesions. No lymph nodes are identified in the hilum of the kidney. Serial cross sections of the left adrenal gland show unremarkable cortex and medulla. Portions of the tumor are submitted for possible electron microscopy and to the Tumor Bank.

SECTION CODE: A1, ureter, renal artery and renal vein margin; A2, A3, tumor in relationship with adrenal gland; A4, A5, tumor with kidney capsule; A6, A7, gelatinous tumor with capsule; A8, A9, tumor with relationship with renal sinus; A10, A11, tumor with renal parenchyma; A12, representative section of adrenal; A13, representative section of uninvolved kidney. [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file fbe07c74-3c3e-4a9a-948e-6de9814a8779 (TCGA-CJ-4903.D48F97BD-9231-42FC-9864-BD43D3EE7536.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).